Somatic mutation profile of tumor specimen TCGA-DX-A3LY-01B (aliquot TCGA-DX-A3LY-01B-11D-A27P-09) from TCGA case TCGA-DX-A3LY, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 66.2 years (24,166 days).
Specimen TCGA-DX-A3LY-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f703e38f-93c7-4c3c-a6c3-20428076fa7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3LY-10B (Blood Derived Normal), aliquot TCGA-DX-A3LY-10B-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b544f7d7-c67b-4474-96df-5aeccfacffdd

The open-access MAF lists 48 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Nonsense Mutation 3, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACCSL | c.981C>A p.N327K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs745906456; called by muse, mutect2, varscan2
- ADD2 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 3/45 reads (7%) | catalogued as COSV52455835; called by muse, mutect2
- AGO4 | c.2452C>A p.H818N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64618930; called by muse, mutect2
- BCR | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100006844; called by muse, mutect2, varscan2
- BRINP3 | c.1800G>T p.K600N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.102); catalogued as COSV66527267; called by muse, mutect2, varscan2
- GTF3C1 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs892440505, COSV62240117; called by muse, mutect2, varscan2
- KRT8 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV53175854, COSV53179166; called by muse, mutect2, varscan2
- LAMA2 | c.4825C>A p.L1609M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV70350725; called by muse, mutect2
- LARGE1 | c.1573A>T p.S525C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs1432918377; called by muse, mutect2, varscan2
- LCT | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as COSV99930208; called by muse, mutect2, varscan2
- NABP2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1320610392; called by muse, mutect2
- RPL36A | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV65717943; called by muse, mutect2, varscan2
- SEZ6L | c.2581C>T p.R861C | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs779505302, COSV50659958; called by muse, mutect2, varscan2
- TET2 | c.3195G>T p.L1065F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54407795; called by mutect2, varscan2
- WDR49 | c.1039C>T p.P347S (on ENST00000308378 / NM_001366158.1; = p.P688S on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100393517; called by muse, mutect2
- ADCY9 | c.3592G>C p.D1198H | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGO4 | c.2294C>A p.S765* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2, varscan2
- ASCC3 | c.1237A>G p.M413V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COX20 | c.185G>C p.G62A | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- CYP4F11 | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.078); called by muse, varscan2
- EGR1 | c.260A>C p.N87T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- EMCN | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- IL16 | c.3982G>T p.A1328S (on ENST00000302987 / NM_172217.5; = p.A627S on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.033); called by muse, mutect2
- KRCC1 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- KRT78 | c.953A>T p.H318L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- MAML1 | c.1811G>A p.S604N | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MMP27 | c.399A>T p.E133D | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MTMR12 | c.950T>A p.L317Q | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR5AR1 | c.287G>C p.S96T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PAPPA2 | c.115C>A p.H39N | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PNPLA3 | c.558del p.F187Sfs*76 | Frame Shift Del (DEL) | VAF 34/103 reads (33%) | called by mutect2, pindel, varscan2
- SPECC1 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ST6GALNAC3 | c.316A>G p.R106G | Missense Mutation (SNP) | VAF 35/78 reads (45%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF1L | c.877C>A p.Q293K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- XIRP2 | c.320T>C p.I107T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZDHHC15 | c.824G>C p.G275A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARID1B | c.5805G>A p.V1935= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs953474187; called by muse, mutect2
- CAMTA1 | c.1329C>T p.A443= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV57911900; called by muse, mutect2, varscan2
- KIF26A | c.2097C>T p.I699= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs772958680; called by muse, mutect2, varscan2
- LRTM2 | c.915G>A p.R305= | Silent (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- MAN1B1 | c.615C>T p.V205= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs1307106295; called by muse, mutect2
- NABP2 | c.75G>A p.E25= | Silent (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2
- OPRL1 | c.60C>A p.G20= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV100402204; called by muse, mutect2
- TKTL2 | c.1671C>A p.G557= | Silent (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- TMC6 | c.1914G>A p.A638= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs751492239; called by muse, mutect2, varscan2
- USP28 | c.2745A>G p.Q915= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- LRRFIP1 | c.748-1290C>G | Intron (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.2424+38G>A | Intron (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
